Somatic mutation profile of tumor specimen C3L-00139-01 (aliquot CPT0001850005) from CPTAC case C3L-00139, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage III; FIGO stage: Stage III; Age at diagnosis: 83.6 years (30,538 days).
Specimen C3L-00139-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 170d24a4-e681-4531-ac88-f2901f20c15e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00139-31 (Blood Derived Normal), aliquot CPT0003950002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0eae8ec3-5b78-44e8-a7f9-d32894c507f3

The open-access MAF lists 106 somatic variants for this specimen: 66 protein-altering or splice-affecting, 25 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 25, Intron 8, Nonsense Mutation 5, Frame Shift Del 2, RNA 2, 5'Flank 2, Splice Site 2, 5'UTR 2, Nonstop Mutation 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1637A>C p.Q546P | Missense Mutation (SNP) | VAF 146/212 reads (69%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PPP2R1A | c.536C>G p.P179R | Missense Mutation (SNP) | VAF 55/307 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs786205228, CM153573, COSV59042232, COSV59042841; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 434/537 reads (81%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCL2L2 | c.188A>T p.D63V | Missense Mutation (SNP) | VAF 106/137 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1270964845; called by muse, mutect2, varscan2
- C1QTNF4 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 126/380 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs750448411; called by muse, mutect2, varscan2
- CEP192 | c.2855T>C p.F952S | Missense Mutation (SNP) | VAF 57/129 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs746520057; called by muse, mutect2, varscan2
- CHST8 | c.1127G>A p.R376Q | Missense Mutation (SNP) | VAF 34/460 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1010872524; called by muse, mutect2
- COL5A1 | c.2725C>T p.R909W | Missense Mutation (SNP) | VAF 54/145 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1257715072, COSV100880665; called by muse, mutect2, varscan2
- DRG2 | c.367G>A p.A123T | Missense Mutation (SNP) | VAF 17/218 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56728190; called by muse, mutect2
- FBXO30 | c.670G>A p.A224T | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs918174400; called by muse, mutect2
- GMIP | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 33/315 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs752888327; called by muse, mutect2, varscan2
- KCNA7 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 87/372 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376824241; called by muse, mutect2, varscan2
- KLRG2 | c.1058G>T p.R353L | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100572459; called by muse, mutect2, varscan2
- MRPS14 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as rs771170204; called by muse, mutect2
- OBSCN | c.5873C>G p.S1958* | Nonsense Mutation (SNP) | VAF 20/474 reads (4%) | catalogued as COSV52795044; called by muse, mutect2
- PCDHGA7 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs761689266, COSV54043689; called by muse, mutect2, varscan2
- PCLO | c.2545G>A p.V849I | Missense Mutation (SNP) | VAF 28/126 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs547726879, COSV61660879; called by muse, mutect2
- PRPF3 | c.2051G>C p.*684Sext*67 | Nonstop Mutation (SNP) | VAF 21/369 reads (6%) | catalogued as COSV61394971; called by muse, mutect2
- PSG1 | c.526G>A p.A176T | Missense Mutation (SNP) | VAF 249/440 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs1475443567, COSV54956672; called by muse, mutect2, varscan2
- PYHIN1 | c.649G>A p.A217T | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as rs1308534208, COSV63723191; called by muse, mutect2
- SHROOM3 | c.3166G>A p.D1056N | Missense Mutation (SNP) | VAF 21/204 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.243); catalogued as rs750605726, COSV56029750; called by muse, mutect2, varscan2
- SLC4A3 | c.2611G>C p.E871Q | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.044); catalogued as rs1418002880; called by muse, mutect2
- TMEM63C | c.1405C>G p.L469V | Missense Mutation (SNP) | VAF 38/298 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.02); catalogued as COSV53603616, COSV53607177; called by muse, mutect2, varscan2
- TULP2 | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 8/196 reads (4%) | catalogued as COSV55478657; called by muse, mutect2
- ZHX2 | c.151C>T p.L51F | Missense Mutation (SNP) | VAF 247/385 reads (64%) | SIFT tolerated (0.15); PolyPhen benign (0.033); catalogued as rs201553642; called by muse, mutect2, varscan2
- ZIM3 | c.541C>T p.R181C | Missense Mutation (SNP) | VAF 32/450 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs557421274, COSV99518821; called by muse, mutect2
- ZNF536 | c.2963C>T p.P988L | Missense Mutation (SNP) | VAF 38/851 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138241491; called by muse, mutect2
- ZNF785 | c.600C>G p.F200L | Missense Mutation (SNP) | VAF 12/166 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.689); catalogued as COSV67876333; called by muse, mutect2
- ACER1 | c.570C>G p.D190E | Missense Mutation (SNP) | VAF 46/188 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ACP3 | c.158T>G p.F53C | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANKRD12 | c.4935G>C p.L1645F | Missense Mutation (SNP) | VAF 13/229 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.296); called by muse, mutect2
- AP5S1 | c.131A>G p.E44G | Missense Mutation (SNP) | VAF 16/410 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- ASMTL | c.1049del p.K350Rfs*77 | Frame Shift Del (DEL) | VAF 62/104 reads (60%) | called by mutect2, pindel, varscan2
- BPIFC | c.665A>C p.K222T | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- CALB1 | c.506+1G>A p.X169_splice | Splice Site (SNP) | VAF 43/229 reads (19%) | called by muse, mutect2, varscan2
- CASP8AP2 | c.1242G>A p.W414* | Nonsense Mutation (SNP) | VAF 54/89 reads (61%) | called by muse, mutect2, varscan2
- CC2D2A | c.3772T>C p.F1258L | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDK12 | c.197T>C p.V66A | Missense Mutation (SNP) | VAF 172/534 reads (32%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- CYP19A1 | c.719T>A p.L240Q | Missense Mutation (SNP) | VAF 56/182 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); called by muse, varscan2
- DPYSL3 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 36/191 reads (19%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- EDEM3 | c.239T>C p.L80S | Missense Mutation (SNP) | VAF 11/322 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FAM53B | c.976_978delinsAGA p.F326R | Missense Mutation (TNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.786); called by muse*, pindel, varscan2*
- FANCE | c.195G>C p.E65D | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.511); called by muse, mutect2
- GHSR | c.954C>G p.I318M | Missense Mutation (SNP) | VAF 74/542 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GLI2 | c.1087A>C p.S363R | Missense Mutation (SNP) | VAF 205/532 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- GRID2IP | c.2405C>T p.P802L | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- GRIK4 | c.2217G>C p.Q739H | Missense Mutation (SNP) | VAF 28/217 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- KCNT2 | c.3234T>G p.S1078R | Missense Mutation (SNP) | VAF 10/184 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.06); called by muse, mutect2
- KIF18A | c.1698C>G p.H566Q | Missense Mutation (SNP) | VAF 49/95 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- LAMA5 | c.2051C>G p.S684C | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LAMB4 | c.945T>A p.D315E | Missense Mutation (SNP) | VAF 6/146 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.57); called by muse, mutect2
- LHFPL6 | c.523G>C p.A175P | Missense Mutation (SNP) | VAF 31/192 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- MAS1 | c.848T>C p.V283A | Missense Mutation (SNP) | VAF 120/173 reads (69%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MYH3 | c.3294G>C p.E1098D | Missense Mutation (SNP) | VAF 72/451 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- NUCB1 | c.130A>G p.S44G | Missense Mutation (SNP) | VAF 78/375 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- PARP8 | c.2090+1G>A p.X697_splice | Splice Site (SNP) | VAF 9/137 reads (7%) | called by muse, mutect2
- PDE3B | c.1978G>C p.D660H | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, mutect2
- PRDM4 | c.2311G>C p.E771Q | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.08); called by muse, mutect2
- RAB19 | c.330C>G p.H110Q | Missense Mutation (SNP) | VAF 23/263 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.933); called by muse, mutect2
- SBF2 | c.2952T>A p.F984L | Missense Mutation (SNP) | VAF 130/229 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- SLC22A8 | c.885+7G>C | Splice Region (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- SLF1 | c.901G>C p.D301H | Missense Mutation (SNP) | VAF 53/82 reads (65%) | SIFT tolerated (0.42); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- TAF1B | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 18/261 reads (7%) | called by muse, mutect2
- TXNIP | c.494_497del p.E165Gfs*65 | Frame Shift Del (DEL) | VAF 30/278 reads (11%) | called by mutect2, pindel, varscan2
- XIRP1 | c.844_846del p.N282del | In Frame Del (DEL) | VAF 54/248 reads (22%) | called by mutect2, pindel, varscan2
- ZNF106 | c.3740G>C p.R1247T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- AASS | c.2454C>T p.L818= | Silent (SNP) | VAF 204/395 reads (52%) | called by muse, mutect2, varscan2
- ADGRB1 | c.324C>G p.L108= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as rs774061860; called by muse, mutect2, varscan2
- CDH24 | c.1326C>T p.R442= | Silent (SNP) | VAF 323/441 reads (73%) | catalogued as rs767768911; called by muse, mutect2, varscan2
- CFAP46 | c.6054G>A p.P2018= | Silent (SNP) | VAF 55/148 reads (37%) | catalogued as rs779521444; called by muse, mutect2, varscan2
- COL17A1 | c.3021C>T p.I1007= | Silent (SNP) | VAF 29/346 reads (8%) | catalogued as COSV62226371; called by muse, mutect2
- DNAAF1 | c.1731G>C p.S577= | Silent (SNP) | VAF 16/110 reads (15%) | catalogued as COSV58989234; called by muse, mutect2, varscan2
- FOXN3 | c.114C>T p.D38= | Silent (SNP) | VAF 23/315 reads (7%) | catalogued as rs370384884; called by muse, mutect2
- FTO | c.1029G>A p.Q343= | Silent (SNP) | VAF 51/372 reads (14%) | called by muse, mutect2, varscan2
- FZD3 | c.1320T>C p.F440= | Silent (SNP) | VAF 25/84 reads (30%) | called by muse, mutect2, varscan2
- GRM1 | c.96G>A p.A32= | Silent (SNP) | VAF 62/434 reads (14%) | called by muse, varscan2
- HS3ST6 | c.933C>T p.R311= | Silent (SNP) | VAF 21/138 reads (15%) | catalogued as rs368901112; called by muse, mutect2, varscan2
- HTRA1 | c.1425C>T p.P475= | Silent (SNP) | VAF 212/417 reads (51%) | catalogued as rs779158785, COSV64565063; called by muse, mutect2, varscan2
- KALRN | c.3900G>A p.L1300= | Silent (SNP) | VAF 148/217 reads (68%) | catalogued as rs755480505; called by muse, mutect2, varscan2
- MOB3C | c.474C>G p.L158= | Silent (SNP) | VAF 31/526 reads (6%) | called by muse, mutect2
- MROH1 | c.4176C>T p.S1392= | Silent (SNP) | VAF 104/449 reads (23%) | catalogued as rs968901869; called by muse, mutect2, varscan2
- MUC16 | c.7671A>G p.T2557= | Silent (SNP) | VAF 17/275 reads (6%) | catalogued as rs950474366; called by muse, mutect2
- NAV3 | c.1188T>A p.A396= | Silent (SNP) | VAF 24/324 reads (7%) | catalogued as COSV99886587; called by muse, mutect2
- PCDHGA4 | c.711G>A p.A237= | Silent (SNP) | VAF 19/202 reads (9%) | catalogued as COSV53935044; called by muse, mutect2
- PKDREJ | c.711G>A p.A237= | Silent (SNP) | VAF 5/51 reads (10%) | catalogued as rs532892775; called by mutect2, varscan2
- RASL10A | c.30A>G p.L10= | Silent (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- RHOXF2 | c.357G>A p.S119= | Silent (SNP) | VAF 49/224 reads (22%) | catalogued as rs782048832, COSV65047646; called by mutect2, varscan2
- SKOR2 | c.363C>T p.R121= | Silent (SNP) | VAF 39/303 reads (13%) | catalogued as rs1410302098, COSV68550270; called by muse, mutect2, varscan2
- TIMELESS | c.3225G>A p.G1075= | Silent (SNP) | VAF 33/111 reads (30%) | called by muse, mutect2, varscan2
- TMEM81 | c.393C>T p.D131= | Silent (SNP) | VAF 33/324 reads (10%) | catalogued as rs149751860; called by muse, mutect2, varscan2
- TRAF2 | c.1494G>C p.L498= | Silent (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2
- ABCB8 | c.1268+563C>T | Intron (SNP) | VAF 12/256 reads (5%) | catalogued as rs1024383819; called by muse, mutect2
- ACKR2 | c.-37-8137C>T | Intron (SNP) | VAF 14/57 reads (25%) | called by muse, mutect2, varscan2
- AMFR | c.*18C>T | 3'UTR (SNP) | VAF 30/322 reads (9%) | called by muse, mutect2
- AMFR | c.1276+370G>A | Intron (SNP) | VAF 66/124 reads (53%) | catalogued as rs1411182389; called by muse, mutect2, varscan2
- ARIH2 | chr3:48918570 C>A | 5'Flank (SNP) | VAF 357/513 reads (70%) | catalogued as COSV62704591; called by muse, mutect2, varscan2
- EPS8L2 | c.895+20G>A | Intron (SNP) | VAF 43/83 reads (52%) | catalogued as rs1371169307; called by muse, mutect2, varscan2
- HRH4 | c.-1G>A | 5'UTR (SNP) | VAF 10/62 reads (16%) | called by muse, varscan2
- HSPA7 | n.883T>G | RNA (SNP) | VAF 39/718 reads (5%) | called by muse, mutect2
- KLF6 | chr10:3785214 del G | 5'Flank (DEL) | VAF 108/429 reads (25%) | called by pindel, varscan2
- MACROD2 | c.859+956C>G | Intron (SNP) | VAF 8/250 reads (3%) | called by muse, mutect2
- SLC13A1 | c.661-2283A>T | Intron (SNP) | VAF 15/174 reads (9%) | called by muse, mutect2
- SNORD115-23 | n.34G>C | RNA (SNP) | VAF 14/180 reads (8%) | called by muse, mutect2
- TMX3 | c.311+117C>G | Intron (SNP) | VAF 9/125 reads (7%) | called by muse, mutect2
- TRA2A | c.37-583C>G | Intron (SNP) | VAF 11/102 reads (11%) | catalogued as COSV51719373; called by muse, mutect2, varscan2
- VPS16 | c.-15C>G | 5'UTR (SNP) | VAF 17/486 reads (3%) | called by muse, mutect2
